Somatic mutation profile of tumor specimen C3L-03740-01 (aliquot CPT0249420006) from CPTAC case C3L-03740, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 77.7 years (28,396 days).
Specimen C3L-03740-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 667d009f-168c-494d-8dba-3a8ea3af4b00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03740-31 (Blood Derived Normal), aliquot CPT0250420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/438bfdd9-f177-4207-8bbd-05f9dbc29f56

The open-access MAF lists 67 somatic variants for this specimen: 37 protein-altering or splice-affecting, 22 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 22, Intron 4, Splice Region 4, RNA 2, Frame Shift Ins 2, Frame Shift Del 1, 3'UTR 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.374C>A p.T125K | Missense Mutation (SNP) | VAF 21/219 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs786201057, CM102351, CM157948, COSV52667346, COSV52673504, COSV52688693, COSV99037266; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ALDH4A1 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 156/480 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1219545012; called by muse, mutect2, varscan2
- BRPF1 | c.665A>G p.Y222C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs753195868; called by muse, mutect2, varscan2
- CD163L1 | c.3644C>T p.T1215M | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as rs774379913, COSV58015111, COSV58026644; called by muse, mutect2, varscan2
- CDH8 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 109/351 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV54864663; called by muse, mutect2, varscan2
- CYP11B1 | c.926T>C p.M309T | Missense Mutation (SNP) | VAF 144/373 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs1261412258; called by muse, mutect2, varscan2
- FCN1 | c.38C>A p.A13D | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.235); catalogued as COSV65662655; called by muse, mutect2, varscan2
- FOLH1 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV57055746; called by muse, mutect2, varscan2
- GAD2 | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as rs772567180; called by muse, mutect2, varscan2
- HCRTR2 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs200545298, COSV63795564; called by muse, mutect2, varscan2
- ITGB6 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764045213; called by muse, mutect2, varscan2
- KIAA0825 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.357); catalogued as COSV56952041; called by muse, mutect2, varscan2
- LAMC2 | c.3310G>A p.G1104S | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs199948334, COSV51459615; called by muse, mutect2, varscan2
- OCA2 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 136/377 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1429075390, COSV62337912; called by muse, mutect2, varscan2
- PCNX4 | c.1359A>G p.V453= (on ENST00000406854 / NM_001330177.2; = p.V219= on NM_022495.5) | Splice Region (SNP) | VAF 38/105 reads (36%) | catalogued as rs781034559, COSV100470439; called by muse, mutect2, varscan2
- PRICKLE1 | c.934G>C p.V312L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV61546445; called by muse, mutect2, varscan2
- SLC22A24 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370756811; called by muse, mutect2, varscan2
- SVOPL | c.605G>A p.R202H (on ENST00000419765; = p.R50H on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/252 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151301864, COSV99065539; called by muse, mutect2, varscan2
- TBX3 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 57/219 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV57473613, COSV57476383; called by muse, mutect2, varscan2
- TENM3 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 109/339 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as COSV101304956, COSV69315310; called by muse, mutect2, varscan2
- TRRAP | c.3210C>G p.S1070R | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs1554412456; called by muse, mutect2, varscan2
- ZNF675 | c.868G>T p.G290C | Missense Mutation (SNP) | VAF 97/313 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV63097314; called by muse, mutect2, varscan2
- DEPDC5 | c.3186-3C>G | Splice Region (SNP) | VAF 50/126 reads (40%) | called by muse, mutect2, varscan2
- EVX2 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 140/401 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GRB14 | c.1318T>C p.F440L | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LIMK1 | c.1319T>C p.F440S | Missense Mutation (SNP) | VAF 34/456 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- MATR3 | c.1224dup p.K409Efs*25 | Frame Shift Ins (INS) | VAF 50/168 reads (30%) | called by mutect2, pindel, varscan2
- NDUFAF6 | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 116/370 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- PCDHB1 | c.2120T>C p.I707T | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHLPP2 | c.-4A>G | Splice Region (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2, varscan2
- SEL1L | c.1729del p.Q577Sfs*29 | Frame Shift Del (DEL) | VAF 68/252 reads (27%) | called by mutect2, pindel, varscan2
- SLC26A7 | c.997A>C p.K333Q | Missense Mutation (SNP) | VAF 114/297 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SPEF2 | c.1669dup p.S557Ffs*5 | Frame Shift Ins (INS) | VAF 58/215 reads (27%) | called by mutect2, pindel, varscan2
- STAG2 | c.2581A>T p.R861* | Nonsense Mutation (SNP) | VAF 46/59 reads (78%) | called by muse, mutect2, varscan2
- TRHDE | c.1255A>G p.I419V | Missense Mutation (SNP) | VAF 82/286 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- TRIOBP | c.2431C>G p.Q811E | Missense Mutation (SNP) | VAF 296/478 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- UNK | c.105G>A p.T35= | Splice Region (SNP) | VAF 72/182 reads (40%) | called by muse, mutect2, varscan2
- ADGRG7 | c.1476C>A p.S492= | Silent (SNP) | VAF 36/210 reads (17%) | called by muse, varscan2
- C11orf95 | c.2010C>T p.L670= | Silent (SNP) | VAF 38/79 reads (48%) | called by muse, mutect2
- CACNA1H | c.3543C>T p.D1181= | Silent (SNP) | VAF 113/271 reads (42%) | catalogued as rs958144782, COSV61987153; called by muse, mutect2, varscan2
- CHD5 | c.5238G>A p.A1746= | Silent (SNP) | VAF 64/176 reads (36%) | catalogued as rs144715774, COSV99312371; called by muse, mutect2, varscan2
- CREB3L3 | c.124C>T p.L42= | Silent (SNP) | VAF 130/337 reads (39%) | catalogued as rs1204578174; called by muse, mutect2, varscan2
- DMRT1 | c.885G>A p.P295= | Silent (SNP) | VAF 131/384 reads (34%) | catalogued as rs771988103, COSV101206605; called by muse, mutect2, varscan2
- FAT3 | c.3873C>T p.I1291= | Silent (SNP) | VAF 56/217 reads (26%) | catalogued as rs775346212; called by muse, mutect2, varscan2
- IGF2BP3 | c.84G>A p.P28= | Silent (SNP) | VAF 45/210 reads (21%) | catalogued as COSV99325636; called by muse, mutect2, varscan2
- LOXHD1 | c.2850C>T p.D950= | Silent (SNP) | VAF 187/467 reads (40%) | catalogued as rs988613821; ClinVar: likely benign; called by muse, mutect2, varscan2
- MCM3AP | c.4218T>A p.I1406= | Silent (SNP) | VAF 32/105 reads (30%) | called by muse, mutect2, varscan2
- MYEOV | c.621G>A p.G207= | Silent (SNP) | VAF 107/298 reads (36%) | catalogued as rs759674711; called by muse, mutect2, varscan2
- NGF | c.630G>A p.A210= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as rs112292538, COSV101049327; called by muse, mutect2, varscan2
- NLRP5 | c.1788C>T p.Y596= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as rs1417105620, COSV66762452; called by muse, mutect2, varscan2
- OR4C13 | c.672G>A p.K224= | Silent (SNP) | VAF 85/288 reads (30%) | catalogued as COSV101634196, COSV101634248; called by muse, mutect2, varscan2
- RCAN1 | c.243C>A p.G81= | Silent (SNP) | VAF 144/361 reads (40%) | called by muse, mutect2, varscan2
- RYR2 | c.7263C>A p.S2421= | Silent (SNP) | VAF 46/145 reads (32%) | catalogued as COSV63682970; called by muse, mutect2, varscan2
- SCYL3 | c.885T>G p.L295= | Silent (SNP) | VAF 62/149 reads (42%) | called by muse, mutect2, varscan2
- SLC16A9 | c.801G>A p.T267= | Silent (SNP) | VAF 83/133 reads (62%) | catalogued as rs748281198, COSV68099268; called by muse, mutect2, varscan2
- SMC4 | c.3213T>C p.S1071= | Silent (SNP) | VAF 76/288 reads (26%) | called by muse, mutect2, varscan2
- SVOPL | c.732C>T p.R244= (on ENST00000419765; = p.R92= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 84/361 reads (23%) | catalogued as rs765138699, COSV55993517; called by muse, mutect2, varscan2
- SYT16 | c.1518G>A p.A506= | Silent (SNP) | VAF 100/237 reads (42%) | catalogued as rs200581957, COSV70854823; called by muse, mutect2, varscan2
- ZBBX | c.1233G>T p.V411= | Silent (SNP) | VAF 25/170 reads (15%) | called by muse, mutect2, varscan2
- DYSF | c.3174+42C>T | Intron (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- MGAM | c.4619-222G>A | Intron (SNP) | VAF 71/320 reads (22%) | catalogued as rs769387358, COSV72075443; called by muse, mutect2, varscan2
- MYO15A | c.*29G>A | 3'UTR (SNP) | VAF 64/203 reads (32%) | called by muse, mutect2, varscan2
- NBPF22P | n.1356C>T | RNA (SNP) | VAF 127/332 reads (38%) | catalogued as rs1242718522; called by muse, mutect2, varscan2
- PABPC1P2 | n.517G>A | RNA (SNP) | VAF 36/113 reads (32%) | called by muse, mutect2, varscan2
- RERG | c.192+22A>C | Intron (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- TMEM120A | c.564-47G>A | Intron (SNP) | VAF 46/177 reads (26%) | catalogued as rs372363121; called by muse, mutect2, varscan2
- ZNF99 | c.-16C>T | 5'UTR (SNP) | VAF 44/140 reads (31%) | catalogued as rs748715231; called by muse, mutect2, varscan2
